Surgical pathology report (de-identified scan), TCGA case TCGA-W7-A93P, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-W7-A93P-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3

Cholangiocarcinoma 8160/3

Site: Common bile duct c24.c

2/16/14

Collected Date:

CLINICAL DETAILS

Histopath: Frozen section common hepatic duct margin. ca pancreas. Whipple's specimen - Histology.

FROZEN SECTION REPORT

1. Examined by frozen section and reported by _____ on _____ as "No evidence of malignancy. Some atypical glands with lobular architecture - No surgical suspicious of involvement, await paraffin".

MACROSCOPIC DESCRIPTION

1. LABELLED 'COMMON HEPATIC DUCT MARGIN'. Two fragments of tissue, the first pale with a red fleshy end, 15 x 3mm. The second fragment of tissue is red, fleshy 4mm triangle. Specimen all embedded for frozen section; 1A separate small fragment and fleshy end fragment; 1B round stringy end pale with other end inked blue. Diagram drawn by _____

2. LABELLED 'WHIPPLE OPERATION SPECIMEN'. Consists of the head of pancreas measuring 70 x 50 x 22mm with duodenum measuring 140mm in length and distal stomach measuring 65mm in length and 70mm in circumference. There is attached common bile duct 30mm in length and common hepatic duct 2mm in length, cystic duct 30mm in length and gallbladder 115 x 45 x 38mm. There is attached greater omentum 130 x 80 x 10mm and lesser omentum 60 x 50 x 5mm. The pancreatic neck resection margin, portal vein groove and uncinate margin have been inked black prior to receipt and the posterior surface of the pancreas inked blue. On opening of the common bile duct, there is a plaque-like pale tumour 21 x 11 x 4mm, situated 27mm from the common hepatic duct margin and 22mm from the cystic duct and 18mm from the ampulla. The tumour is centered on the medial wall of the common bile duct. The common bile duct proximal to the tumour measures 33mm in diameter and distal to the tumour measures 6mm in diameter. On sectioning of the bile duct tumour, the tumour appears to invade the wall of the bile duct and possibly invade the pancreas. The tumour appears to be situated 11mm from the posterior resection margin. The tumour has a maximum depth of 6mm. Block 2A stomach resection margin; 2B representative section of stomach; 2C pylorus; 2D distal duodenal resection margin; 2E shave of common hepatic duct margin; 2F cystic duct; 2G-2H pancreatic neck resection margin in longitudinal sections; 2I-2M uncinate process resection margin as longitudinal sections; 2N-2P inferior pancreatic resection margin as longitudinal sections; 2Q-2S portal vein groove margin as longitudinal sections; 2T-2U anterior margin Representative sections; 2V-2Y posterior margin longitudinal sections (block 2X and 2Y containing common bile duct tumour); 2Z ampulla of Vater; 2AA-2AC tumour (tumour all embedded); 2AD 1 node; 2AE 1 node in four pieces; 2AF 1 node in three pieces (2AD-2AF lymph nodes from region of bile duct); 2AG 4 nodes (from superior aspect of pancreas); 2AH 5 nodes; 2AJ 1 node (2AH-2AJ lymph nodes in region of greater curve of stomach); 2AK Representative sections of body and fundus of gallbladder.

MICROSCOPIC REPORT

SYNOPTIC REPORT FOR TUMOURS IN PANCREATIC RESECTIONS

TYPE OF SPECIMEN: Whipple's resection.

[page 2 of 3]
lected Date:

TUMOUR DETAILS:

Site of tumour: Common bile duct.

Size of tumour (mm): 21mm.

Histological type: Infiltrating adenocarcinoma.

Tumour grade: Moderately differentiated.

Carcinoma in situ: Absent.

EXTENT OF LOCAL INVASION:

Direct spread:

- Peri-pancreatic/common bile duct fat: Present.
- Wall of duodenum: Absent.
- Other (specify): Invasion into adjacent pancreas.

Vascular invasion:

- Small vessel/lymphovascular invasion: Absent.
- Large vessel/venous invasion: Absent.

Perineural invasion: Present.

RESECTION MARGINS:

Invasive: 0.5mm to the portal vein groove/bed (block 2S). 4mm to the posterior retroperitoneal margin (block 2X). 27mm to the common bile duct resection margin and well clear of other margins.

Carcinoma in situ: Not applicable.

LYMPH NODES:

Total lymph nodes: Sixteen (16).

Numbers involved: Zero (0).

pTNM STAGING (AJCC 2002): T3 N0 Mx

OTHER FEATURES:

- The gallbladder is unremarkable.
- The stomach shows mild non-specific chronic gastritis.
- The ampulla is unremarkable.

[page 3 of 3]
lected Date:

SUMMARY

1. Common hepatic duct margin - No evidence of malignancy.
2. Whipple specimen - Infiltrative adenocarcinoma arising from common bile duct.

Printed:

Page 3 of 3

Source: NCI Genomic Data Commons file 50b5e400-6ada-4ec3-82df-c265bccb5fbe (TCGA-W7-A93P.B92ED842-5178-4E6E-AB1F-6B121B5BC633.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).